Somatic mutation profile of tumor specimen C3L-00561-01 (aliquot CPT0023350006) from CPTAC case C3L-00561, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 50.6 years (18,481 days).
Specimen C3L-00561-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72d50ab7-ac08-458c-879e-4bfac7219d59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00561-31 (Blood Derived Normal), aliquot CPT0024550002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62a52fc7-e395-407c-b828-6f372bd6188b

The open-access MAF lists 83 somatic variants for this specimen: 52 protein-altering or splice-affecting, 15 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 15, Intron 6, 3'UTR 3, 5'Flank 3, Nonsense Mutation 3, 5'UTR 2, Frame Shift Del 2, RNA 2, Splice Site 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF12 | c.2977C>A p.R993S | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63104399; called by muse, mutect2, varscan2
- AXL | c.487C>G p.Q163E | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as COSV99995846; called by muse, mutect2
- COL1A2 | c.2056C>T p.P686S | Missense Mutation (SNP) | VAF 132/518 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV51958747; called by muse, mutect2, varscan2
- DGCR8 | c.1371A>T p.K457N | Missense Mutation (SNP) | VAF 30/370 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV61227912; called by muse, mutect2
- DMBT1 | c.2398G>T p.V800L | Missense Mutation (SNP) | VAF 162/667 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.551); catalogued as COSV100352278, COSV100353818; called by muse, mutect2, varscan2
- ERGIC3 | c.527C>G p.P176R | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.766); catalogued as rs1198140249; called by muse, mutect2
- FIBCD1 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.166); catalogued as rs568093970; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.996); catalogued as rs1280642347, COSV101198181; called by mutect2, varscan2
- KRTAP19-7 | c.172T>C p.W58R | Missense Mutation (SNP) | VAF 64/344 reads (19%) | SIFT tolerated, low confidence (0.85); PolyPhen possibly damaging (0.766); catalogued as rs904265716, COSV58366443; called by muse, mutect2, varscan2
- MTOR | c.7501A>T p.I2501F | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV63871874; called by muse, mutect2, varscan2
- MYH11 | c.3124C>T p.R1042W | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs774490005, COSV55547049; ClinVar: uncertain significance; called by muse, mutect2
- NODAL | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs751847569; called by muse, mutect2, varscan2
- NT5DC1 | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1396151216; called by muse, mutect2
- OR5D16 | c.175A>G p.T59A | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV65722554; called by muse, mutect2, varscan2
- SYCP2L | c.427T>A p.F143I | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV51657215; called by muse, mutect2, varscan2
- TMPRSS15 | c.2908G>C p.D970H | Missense Mutation (SNP) | VAF 18/437 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53037014; called by muse, mutect2
- TTC13 | c.794A>G p.Y265C | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768325278; called by muse, varscan2
- VHL | c.329A>C p.H110P | Missense Mutation (SNP) | VAF 96/273 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.917); catalogued as COSV56542926, COSV56543186, COSV56552304; called by muse, mutect2, varscan2
- ZIC4 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 9/213 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV67172967; called by muse, mutect2
- ABCA10 | c.340T>G p.S114A | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- ADGRF5 | c.1969A>C p.M657L | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- ALKBH8 | c.1940T>A p.I647N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- APOB | c.13683C>G p.I4561M | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.073); called by muse, mutect2
- ARFGEF2 | c.5189C>T p.A1730V | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2
- BIVM-ERCC5 | c.962A>T p.Y321F | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BTBD8 | c.3938A>G p.Y1313C (on ENST00000636805 / NM_001376131.1; = p.Y800C on NM_015237.4) | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAND1 | c.932A>T p.Y311F | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- DMRTC1 | c.569T>G p.L190R | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- EIF4ENIF1 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ENPP1 | c.831del p.N277Kfs*8 | Frame Shift Del (DEL) | VAF 10/87 reads (11%) | called by mutect2, pindel, varscan2
- ESR1 | c.1762G>A p.A588T | Missense Mutation (SNP) | VAF 8/191 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.229); called by muse, mutect2
- HCRTR2 | c.1121A>C p.E374A | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.318); called by muse, mutect2
- IQUB | c.1209del p.F403Lfs*8 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | called by mutect2, pindel
- ITGA1 | c.2143_2145del p.I715del | In Frame Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- ITSN1 | c.3563A>G p.E1188G | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2
- KCTD15 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KEAP1 | c.785T>G p.F262C | Missense Mutation (SNP) | VAF 55/439 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- LARP7 | c.387+3A>T | Splice Region (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- MACF1 | c.6409C>A p.L2137M | Missense Mutation (SNP) | VAF 50/136 reads (37%) | called by muse, mutect2, varscan2
- MSTO1 | c.986G>A p.C329Y | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- NLGN4Y | c.1937A>G p.N646S | Missense Mutation (SNP) | VAF 63/405 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- NNMT | c.70T>C p.Y24H | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); called by muse, mutect2
- NUFIP2 | c.1942G>T p.E648* | Nonsense Mutation (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2
- OAS3 | c.1804A>C p.I602L | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- OR5K2 | c.788A>G p.N263S | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.074); called by muse, mutect2
- OXR1 | c.500C>A p.S167* (on ENST00000442977 / NM_001198532.1; = p.S166* on NM_018002.3) | Nonsense Mutation (SNP) | VAF 26/260 reads (10%) | called by muse, mutect2
- PFKL | c.1155C>G p.Y385* | Nonsense Mutation (SNP) | VAF 10/266 reads (4%) | called by muse, mutect2
- ROBO2 | c.34A>C p.M12L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPP40 | c.918A>T p.L306F | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- SLC16A4 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.077); called by muse, mutect2
- SNTN | c.111-1G>A p.X37_splice | Splice Site (SNP) | VAF 12/91 reads (13%) | called by muse, varscan2
- WNK1 | c.6340A>T p.I2114F (on ENST00000315939 / NM_018979.4; = p.I1866F on NM_014823.3) | Missense Mutation (SNP) | VAF 64/565 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- CELSR3 | c.2640C>T p.I880= | Silent (SNP) | VAF 43/254 reads (17%) | called by muse, mutect2, varscan2
- CLTC | c.750C>G p.V250= | Silent (SNP) | VAF 9/153 reads (6%) | catalogued as COSV52244696; called by muse, mutect2
- EP300 | c.2856A>G p.S952= | Silent (SNP) | VAF 61/316 reads (19%) | called by muse, mutect2, varscan2
- FOXR2 | c.411G>A p.E137= | Silent (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- KANK1 | c.792C>A p.R264= | Silent (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- OR10W1 | c.228C>G p.T76= | Silent (SNP) | VAF 38/207 reads (18%) | called by muse, mutect2, varscan2
- OR5T3 | c.177G>T p.V59= | Silent (SNP) | VAF 26/161 reads (16%) | catalogued as rs747953807; called by muse, mutect2, varscan2
- OR6C1 | c.111C>A p.I37= | Silent (SNP) | VAF 25/238 reads (11%) | called by muse, mutect2, varscan2
- PCDHB14 | c.660G>A p.P220= | Silent (SNP) | VAF 39/174 reads (22%) | called by muse, mutect2, varscan2
- PHLPP2 | c.1512C>G p.L504= | Silent (SNP) | VAF 14/324 reads (4%) | called by muse, mutect2
- POLR1A | c.4689C>G p.L1563= | Silent (SNP) | VAF 53/354 reads (15%) | called by muse, mutect2, varscan2
- PTK7 | c.2532G>A p.R844= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as COSV57847318; called by muse, mutect2
- SMCHD1 | c.5601T>A p.I1867= | Silent (SNP) | VAF 38/141 reads (27%) | called by muse, mutect2, varscan2
- USHBP1 | c.1368C>G p.P456= | Silent (SNP) | VAF 21/172 reads (12%) | called by muse, mutect2, varscan2
- USP31 | c.3996A>G p.K1332= | Silent (SNP) | VAF 62/200 reads (31%) | called by muse, mutect2
- AC006372.4 | n.487G>A | RNA (SNP) | VAF 42/300 reads (14%) | catalogued as rs1464034104; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504322 ACAG>TTTT | 5'Flank (ONP) | VAF 4/46 reads (9%) | called by pindel, varscan2*
- ATG4B | chr2:241637443 C>G | 5'Flank (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- CPLANE1 | c.*5820C>T | 3'UTR (SNP) | VAF 18/195 reads (9%) | catalogued as rs146959185; called by muse, mutect2
- FKBP11 | c.388+177G>A | Intron (SNP) | VAF 12/239 reads (5%) | called by muse, mutect2
- GIGYF2 | c.*16_*48del | 3'UTR (DEL) | VAF 29/366 reads (8%) | called by mutect2, pindel
- GNAO1 | c.119-12G>A | Intron (SNP) | VAF 13/127 reads (10%) | called by muse, mutect2, varscan2
- KCNC3 | chr19:50333869 del G | 5'Flank (DEL) | VAF 28/112 reads (25%) | called by mutect2, pindel
- NOP56 | c.1010+135G>T | Intron (SNP) | VAF 21/187 reads (11%) | called by muse, mutect2, varscan2
- RAB12 | c.288-41T>A | Intron (SNP) | VAF 55/200 reads (28%) | called by muse, mutect2, varscan2
- SLC25A21 | c.-208C>T | 5'UTR (SNP) | VAF 46/279 reads (16%) | called by muse, mutect2, varscan2
- TERT | c.-43C>G | 5'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- TMEM184A | c.645-451C>T | Intron (SNP) | VAF 15/167 reads (9%) | called by muse, mutect2
- UBBP4 | n.929G>T | RNA (SNP) | VAF 118/444 reads (27%) | called by muse, mutect2, varscan2
- ZNF211 | c.90+420C>T | Intron (SNP) | VAF 15/174 reads (9%) | catalogued as COSV53745472; called by muse, mutect2
- ZNF99 | c.*3282G>C | 3'UTR (SNP) | VAF 8/131 reads (6%) | called by muse, mutect2
